Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5524, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5524-01A (Primary Tumor).

The patient is a [REDACTED] with a history of prostatic adenocarcinoma with Gleason Score 4 + 4 = 8 on [REDACTED] the left side. PSA 3.76 ng/ml. Clinical TMN stage= cT2b.
PRE-OP DIAGNOSIS: Prostate cancer.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Radical retropubic prostatectomy.

TCGA - EJ - 5524

FINAL DIAGNOSIS:

PART 1:

LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN EIGHT LYMPH NODES (0/8).

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN NINE LYMPH NODES (0/9).

PART 3:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 4+5=9 WITH TERTIARY GLEASON PATTERN 3 COMPONENT.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 2 cm (slide 3EE).
- C. THE CARCINOMA INVOLVES APPROXIMATELY 15% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS EVIDENCE OF ESTABLISHED EXTRACAPSULAR EXTENSION IN THE RIGHT POSTERIOR BASE (slide 3U).
- E. BILATERAL SEMINAL VESICLES AND VASA DEFERENTIA ARE FREE OF CARCINOMA.
- F. ALL EXAMINED SURGICAL MARGINS ARE FREE OF CARCINOMA.
- G. MULTIFOCAL PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA AND INTRADUCTAL EXTENSION OF CARCINOMA ARE IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT3a N0 MX.
- K. NON NEOPLASTIC PROSTATE WITH FOCAL NODULAR HYPERPLASIA, GLANDULAR ATROPHY, AND CHRONIC INFLAMMATION ARE NOTED (see synoptic).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 3.76
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	5
GLEASON SUM SCORE:	9
GLEASON 4/5 PERCENTAGE:	80%
WEIGHT OF PROSTATE:	43.04gm
TUMOR SIZE:	Maximum dimension: 2.0 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	No
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	17
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated
Comment:	Gleason score 4+5=9 with tertiary 3

Extracapsular extension in Rt posterior base (slide 3U)

Source: NCI Genomic Data Commons file 835e0b6d-fdda-4e23-8e47-2b80a9c957de (TCGA-EJ-5524.1F767C93-41F5-45D1-917F-3F1FC5330FB9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).